Gene-level copy-number profile of tumor specimen TCGA-63-7020-01A from TCGA case TCGA-63-7020, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-7020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b42cb784-f38e-4ca3-bec7-a6993c351a79.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-7020-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0178ff10-8598-4608-bd97-95a8bd11698c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 183; copy number 2: 23,084; copy number 3: 15,668; copy number 4: 11,084; copy number 5: 7,494; copy number 6: 2,152; copy number 7: 15; copy number 8: 94; copy number 22: 16; copy number 32: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-7020-01A-11D-1943-01): tumor purity 0.48, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:10,672,628–11,201,833, 12 genes (within-gene range 0–3): C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3.
- chr10:87,503,881–88,259,372, 17 genes: MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,772 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5 (broad region; genes not listed).
- chr4:142,933,195–143,557,486, 14 genes, copy number 22 (within-gene range 2–22): AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1.
- chr4:143,559,472–143,762,093, 3 genes, copy number 22–32: GUSBP5, FREM3, AC104090.1.
- chr5:58,198–51,167,647, 724 genes, copy number 5 (broad region; genes not listed).
- chr7:81,489,204–82,443,777, 5 genes, copy number 6 (within-gene range 4–6): AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1.
- chr7:85,421,122–127,253,093, 695 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:22,219,703–71,702,786, 835 genes, copy number 5–8 (broad region; genes not listed).
- chr8:85,642,777–145,066,685, 945 genes, copy number 5 (broad region; genes not listed).
- chr11:4,859,610–5,678,434, 67 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:66,767–34,166,954, 846 genes, copy number 5 (broad region; genes not listed).
- chr14:48,262,021–86,161,500, 758 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:30,553,956–58,605,223, 1,622 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
